Somatic mutation profile of tumor specimen MP2PRT-PATFHS-TMP1-A (aliquot MP2PRT-PATFHS-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATFHS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,541 days).
Specimen MP2PRT-PATFHS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1026f9b-daa2-47b6-b34d-3268fb8f29ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATFHS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATFHS-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/156dd1fb-969a-48e9-9fa5-ae2a3ccb7be3

The open-access MAF lists 128 somatic variants for this specimen: 76 protein-altering or splice-affecting, 47 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 47, Nonsense Mutation 5, Intron 3, RNA 1, Splice Region 1, 3'UTR 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 110/331 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 251/326 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 37/802 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs782300766, COSV54351658; called by muse, mutect2
- ADGRD2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 279/763 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as rs1224977572; called by muse, mutect2
- CAMTA2 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 190/646 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as rs747897316; called by muse, mutect2, varscan2
- CHRNA5 | c.150G>T p.L50F | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449551218; called by muse, mutect2, varscan2
- CLDN18 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 187/522 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs1208960210, COSV51737863; called by muse, mutect2, varscan2
- COL6A1 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 148/893 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs372619016; called by muse, mutect2, varscan2
- COL6A2 | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 180/916 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553174831; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A2 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 252/381 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65607132; called by muse, mutect2, varscan2
- COL9A2 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 252/378 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101025634; called by muse, mutect2, varscan2
- CYP4A11 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 232/342 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs370892962, COSV60224540; called by muse, mutect2, varscan2
- DNAH2 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 221/792 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.454); catalogued as rs145790522; called by muse, mutect2, varscan2
- FMO2 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 147/408 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.056); catalogued as rs147029269; called by muse, mutect2, varscan2
- KCNQ5 | c.2770C>T p.L924F | Missense Mutation (SNP) | VAF 85/374 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.521); catalogued as rs1402416247; called by muse, mutect2, varscan2
- KLF15 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 177/465 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.267); catalogued as rs141580039, COSV56181050; called by muse, mutect2, varscan2
- KRT4 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 140/374 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs758810156, COSV53407310; called by muse, mutect2, varscan2
- KRTAP4-3 | c.335C>A p.P112H | Missense Mutation (SNP) | VAF 266/1080 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66940882; called by muse, mutect2, varscan2
- MCF2L | c.1397C>T p.T466M (on ENST00000375608; = p.T434M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/465 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs751741111, COSV65047726; called by muse, mutect2, varscan2
- MLLT3 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 13/358 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.155); catalogued as rs1346100633; called by muse, mutect2
- MUC2 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 165/445 reads (37%) | SIFT deleterious (0); catalogued as rs897904604, COSV100364584; called by muse, mutect2, varscan2
- PAFAH1B1 | c.570C>T p.G190= | Splice Region (SNP) | VAF 92/394 reads (23%) | catalogued as rs758682063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA6 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 26/949 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.603); catalogued as rs561019835, COSV65343652; called by muse, mutect2
- RASAL1 | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 183/604 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs767981036, COSV55654133; called by muse, mutect2, varscan2
- SHANK1 | c.4249C>T p.R1417C | Missense Mutation (SNP) | VAF 298/805 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs1158218013; called by muse, mutect2, varscan2
- SORBS1 | c.3644C>T p.P1215L (on ENST00000361941 / NM_001034954.2; = p.P607L on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/275 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53367642; called by muse, mutect2, varscan2
- SPATA18 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 98/414 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs748597597, COSV54644915, COSV54647498; called by muse, mutect2, varscan2
- SPTA1 | c.2313G>C p.L771F | Missense Mutation (SNP) | VAF 121/395 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63753855; called by muse, mutect2, varscan2
- TRPV3 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 190/368 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1339758517, COSV56790671; called by muse, mutect2, varscan2
- ZFHX4 | c.4468G>A p.E1490K | Missense Mutation (SNP) | VAF 144/506 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs747810727; called by muse, mutect2, varscan2
- ZNF674 | c.919C>G p.P307A | Missense Mutation (SNP) | VAF 136/291 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs1303304611; called by muse, mutect2, varscan2
- ZNF723 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs1198325222; called by muse, mutect2, varscan2
- ABCA3 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 222/639 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- AMOT | c.3200C>T p.P1067L (on ENST00000371959 / NM_001113490.1; = p.P658L on NM_133265.3) | Missense Mutation (SNP) | VAF 122/300 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); called by muse, varscan2
- ANGEL1 | c.963C>A p.Y321* | Nonsense Mutation (SNP) | VAF 98/374 reads (26%) | called by muse, mutect2, varscan2
- ANO2 | c.373G>A p.G125R (on ENST00000356134 / NM_001278597.3; = p.G129R on NM_001278596.3) | Missense Mutation (SNP) | VAF 40/822 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.723); called by muse, mutect2
- ATF2 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 154/490 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BEND4 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 32/1058 reads (3%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.015); called by muse, mutect2
- C4orf54 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 118/501 reads (24%) | called by muse, mutect2, varscan2
- CRHR2 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 21/438 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CRYBG2 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 303/438 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- DGKK | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 280/695 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- EGFR | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 85/277 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- FN1 | c.2394G>T p.E798D | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- GLDN | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 252/658 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA6L10 | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 86/1243 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.316); called by muse, mutect2
- GPNMB | c.1262C>T p.P421L (on ENST00000381990 / NM_001005340.2; = p.P409L on NM_002510.3) | Missense Mutation (SNP) | VAF 83/251 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- GPR137B | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 174/450 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- GRAMD1B | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 135/411 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV8-61 | c.364_367del p.I122del | Frame Shift Del (DEL) | VAF 82/226 reads (36%) | called by mutect2, pindel*, varscan2
- ITGAV | c.1468A>T p.T490S | Missense Mutation (SNP) | VAF 86/261 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, varscan2
- KANTR | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- KRT12 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 99/502 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- LGI4 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 270/710 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- LRATD1 | c.671G>C p.R224P | Missense Mutation (SNP) | VAF 193/624 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- LRP4 | c.2970G>A p.M990I | Missense Mutation (SNP) | VAF 151/492 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAP9 | c.1564A>T p.K522* | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- NAGPA | c.1015A>G p.T339A | Missense Mutation (SNP) | VAF 222/637 reads (35%) | PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PAFAH1B1 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 91/396 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLAGL1 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 181/691 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, varscan2
- PLEKHG3 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 182/632 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RGS9 | c.1017G>T p.K339N | Missense Mutation (SNP) | VAF 96/341 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTP2 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 118/437 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- SLC4A5 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 137/501 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC6A15 | c.1141A>G p.M381V | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TGFB2 | c.308T>G p.V103G | Missense Mutation (SNP) | VAF 45/369 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TMEM260 | c.2026C>T p.Q676* | Nonsense Mutation (SNP) | VAF 198/723 reads (27%) | called by muse, mutect2, varscan2
- TNRC6C | c.4664G>A p.R1555Q | Missense Mutation (SNP) | VAF 97/595 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TRRAP | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 77/206 reads (37%) | called by muse, mutect2, varscan2
- TSPY1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 24/872 reads (3%) | SIFT tolerated (0.91); PolyPhen benign (0.027); called by muse, mutect2
- TTC21B | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 123/367 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGGT1 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); called by muse, mutect2
- ZFHX4 | c.281A>T p.K94I | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ZFYVE27 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 18/480 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFYVE27 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 17/480 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF454 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 110/322 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL1 | c.3573G>C p.L1191= | Silent (SNP) | VAF 20/643 reads (3%) | called by muse, mutect2
- ADCY8 | c.2376C>T p.S792= | Silent (SNP) | VAF 126/343 reads (37%) | catalogued as rs770876118, COSV53904387, COSV53921507; called by muse, mutect2, varscan2
- ADH1A | c.372G>T p.L124= | Silent (SNP) | VAF 75/308 reads (24%) | called by muse, mutect2, varscan2
- C4orf54 | c.609C>T p.V203= | Silent (SNP) | VAF 115/491 reads (23%) | called by muse, mutect2, varscan2
- CAMTA2 | c.1563C>T p.I521= | Silent (SNP) | VAF 193/655 reads (29%) | catalogued as COSV61834361; called by muse, mutect2, varscan2
- COL4A1 | c.1365C>T p.G455= | Silent (SNP) | VAF 118/370 reads (32%) | catalogued as rs576636085; called by muse, mutect2, varscan2
- COL6A2 | c.1788C>T p.T596= | Silent (SNP) | VAF 207/1058 reads (20%) | catalogued as rs1227692388; called by muse, mutect2, varscan2
- CRTAC1 | c.924C>T p.I308= | Silent (SNP) | VAF 30/622 reads (5%) | catalogued as COSV54001902; called by muse, mutect2
- DGKI | c.3132T>G p.A1044= | Silent (SNP) | VAF 140/429 reads (33%) | called by muse, mutect2, varscan2
- DNAH3 | c.6384C>T p.F2128= | Silent (SNP) | VAF 26/438 reads (6%) | catalogued as rs537151189, COSV54508561; called by muse, mutect2
- DNMT3B | c.1092T>A p.R364= | Silent (SNP) | VAF 81/549 reads (15%) | called by muse, mutect2, varscan2
- FILIP1 | c.1761T>A p.S587= | Silent (SNP) | VAF 92/406 reads (23%) | called by muse, mutect2, varscan2
- GFER | c.6G>A p.A2= | Silent (SNP) | VAF 137/412 reads (33%) | catalogued as rs891725532; called by muse, mutect2, varscan2
- GRM1 | c.75G>A p.R25= | Silent (SNP) | VAF 142/549 reads (26%) | called by muse, mutect2, varscan2
- HTR1B | c.681C>T p.L227= | Silent (SNP) | VAF 163/664 reads (25%) | called by muse, mutect2, varscan2
- KCNQ5 | c.2262C>T p.L754= | Silent (SNP) | VAF 225/743 reads (30%) | called by muse, mutect2, varscan2
- LOX | c.93C>T p.P31= | Silent (SNP) | VAF 193/561 reads (34%) | called by muse, mutect2, varscan2
- LSMEM1 | c.180G>A p.R60= | Silent (SNP) | VAF 144/365 reads (39%) | called by muse, mutect2, varscan2
- MAP9 | c.1563G>A p.E521= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV60905885; called by muse, mutect2, varscan2
- NAALADL2 | c.1842A>G p.A614= | Silent (SNP) | VAF 136/353 reads (39%) | called by muse, mutect2, varscan2
- NCOR2 | c.5787C>T p.L1929= | Silent (SNP) | VAF 265/682 reads (39%) | catalogued as rs1002655448; called by muse, mutect2, varscan2
- NGFR | c.774C>T p.I258= | Silent (SNP) | VAF 134/687 reads (20%) | catalogued as rs1469549998; called by muse, mutect2, varscan2
- NOTUM | c.615C>T p.A205= | Silent (SNP) | VAF 220/775 reads (28%) | catalogued as rs1334894896; called by muse, mutect2, varscan2
- OR2T34 | c.235C>T p.L79= | Silent (SNP) | VAF 185/610 reads (30%) | called by muse, mutect2, varscan2
- PDHA2 | c.591G>A p.A197= | Silent (SNP) | VAF 181/668 reads (27%) | catalogued as rs757291010, COSV54777134; called by muse, mutect2, varscan2
- PDYN | c.249G>A p.G83= | Silent (SNP) | VAF 23/669 reads (3%) | called by muse, mutect2
- PIGO | c.273T>C p.P91= | Silent (SNP) | VAF 156/496 reads (31%) | called by muse, mutect2, varscan2
- PLAGL1 | c.333C>T p.A111= | Silent (SNP) | VAF 201/750 reads (27%) | catalogued as rs1319609392; called by muse, mutect2, varscan2
- PLCL1 | c.1575C>T p.S525= | Silent (SNP) | VAF 109/397 reads (27%) | called by muse, mutect2, varscan2
- SEMA3E | c.34C>T p.L12= | Silent (SNP) | VAF 154/499 reads (31%) | called by muse, mutect2, varscan2
- SHPRH | c.4731C>T p.I1577= (on ENST00000275233 / NM_001042683.3; = p.I1581= on NM_173082.3) | Silent (SNP) | VAF 112/497 reads (23%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.1911C>T p.F637= | Silent (SNP) | VAF 155/465 reads (33%) | called by muse, mutect2, varscan2
- SLC37A2 | c.1323C>T p.S441= | Silent (SNP) | VAF 130/360 reads (36%) | catalogued as rs1165081107; called by muse, mutect2, varscan2
- SLIT2 | c.825C>T p.A275= | Silent (SNP) | VAF 126/599 reads (21%) | catalogued as rs557268494, COSV56580284; called by muse, mutect2, varscan2
- SOHLH2 | c.909C>T p.S303= | Silent (SNP) | VAF 131/393 reads (33%) | called by muse, mutect2, varscan2
- ST14 | c.2058C>T p.A686= | Silent (SNP) | VAF 225/603 reads (37%) | catalogued as rs759157040; called by muse, mutect2, varscan2
- TAOK2 | c.2952C>T p.G984= | Silent (SNP) | VAF 144/560 reads (26%) | catalogued as rs769442595, COSV99665175; called by muse, varscan2
- TAOK2 | c.2953C>T p.L985= | Silent (SNP) | VAF 144/559 reads (26%) | called by muse, varscan2
- TENT5A | c.291G>A p.P97= | Silent (SNP) | VAF 201/944 reads (21%) | catalogued as rs757159919; called by muse, mutect2, varscan2
- TEX15 | c.4566C>T p.T1522= (on ENST00000256246; = p.T1905= on NM_001350162.2) | Silent (SNP) | VAF 69/259 reads (27%) | called by muse, mutect2, varscan2
- TLN2 | c.3999G>A p.A1333= | Silent (SNP) | VAF 131/356 reads (37%) | catalogued as rs147516120; called by muse, mutect2, varscan2
- TRMT1L | c.423C>T p.L141= | Silent (SNP) | VAF 96/354 reads (27%) | called by muse, mutect2, varscan2
- TRRAP | c.6300C>T p.F2100= (on ENST00000359863 / NM_001244580.1; = p.F2082= on NM_003496.3) | Silent (SNP) | VAF 24/505 reads (5%) | catalogued as rs782336596, COSV62844887; called by muse, mutect2
- TTC22 | c.852C>T p.F284= | Silent (SNP) | VAF 282/403 reads (70%) | catalogued as rs1420445146; called by muse, mutect2, varscan2
- TTN | c.18661C>T p.L6221= (on ENST00000591111; = p.L5294= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 120/394 reads (30%) | catalogued as COSV59966227; called by muse, mutect2, varscan2
- URB1 | c.6417C>T p.L2139= | Silent (SNP) | VAF 205/959 reads (21%) | called by muse, mutect2, varscan2
- ZC3HAV1L | c.588C>T p.S196= | Silent (SNP) | VAF 104/353 reads (29%) | catalogued as COSV51965130; called by muse, mutect2, varscan2
- NEDD4L | c.297+4052C>T | Intron (SNP) | VAF 364/982 reads (37%) | catalogued as rs564450172; called by muse, mutect2
- OPRM1 | c.1165-11154G>A | Intron (SNP) | VAF 128/606 reads (21%) | catalogued as rs1216383688; called by muse, mutect2, varscan2
- PKD1L2 | n.938C>T | RNA (SNP) | VAF 137/413 reads (33%) | catalogued as rs572454755; called by muse, mutect2, varscan2
- STARD3 | c.*139G>A | 3'UTR (SNP) | VAF 164/657 reads (25%) | called by muse, mutect2
- TTN | c.10360+1872G>A | Intron (SNP) | VAF 55/146 reads (38%) | called by muse, mutect2, varscan2
